MMRF case MMRF_1598 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1133db7d-6bbb-4c2a-8649-264b9d69e216

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 45 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.9 years (25,157 days); ISS stage: III; Days to last known disease status: 45 days; Days to last follow up: 45 days.
   Treatment given: Therapeutic agents: Dexamethasone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 45 days.

Follow-up (2 entries)
- Days to follow up: -6 days; ECOG performance status: 0.
- Follow-up contact recording only the day: day 45.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Absolute Neutrophil 5.38 ×10⁹/L.
- Leukocytes 7.58 ×10⁹/L.
- Calcium 2.63 mmol/L.
- Glucose 5.56 mmol/L.
- Hemoglobin 7.38 mmol/L.
- Creatinine 769 µmol/L.
- Immunoglobulin A 0.1 g/L.
- Immunoglobulin M 0.2 g/L.
- Platelets 164 ×10⁹/L.
- Beta 2 Microglobulin 35.3 µg/mL.
- Serum Free Immunoglobulin Light Chain, Kappa 319 mg/dL.
- Blood Urea Nitrogen 20 mmol/L.
- Total Protein 6.2 g/dL.
- Albumin 42 g/L.
- M Protein 0 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.668 mg/dL.
- Immunoglobulin G 1.71 g/L.

Other clinical attributes
- Day -6: Weight: 66 kg; Height: 161 cm.

Biospecimens (2 samples)
- Sample MMRF_1598_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1598_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
